Somatic mutation profile of tumor specimen TCGA-4Z-AA7R-01A (aliquot TCGA-4Z-AA7R-01A-11D-A391-08) from TCGA case TCGA-4Z-AA7R, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 73.3 years (26,781 days).
Specimen TCGA-4Z-AA7R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f255e25c-5d72-4d5f-8fb0-cc33e3d8e10d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4Z-AA7R-10A (Blood Derived Normal), aliquot TCGA-4Z-AA7R-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90febf98-6fb6-43c4-a59f-4c8473f593b0

The open-access MAF lists 407 somatic variants for this specimen: 299 protein-altering or splice-affecting, 101 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 257, Silent 101, Nonsense Mutation 25, Splice Site 8, Frame Shift Del 4, Intron 3, Splice Region 3, In Frame Del 2, RNA 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 35/41 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913381, CM071585, CM973278, COSV58682998, COSV58690035, COSV58690777, COSV58726216; ClinVar: likely pathogenic; called by muse, varscan2
- CDKN2A | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 19/20 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11552822, CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- ABCG5 | c.1111C>T p.L371F | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV53210478; called by muse, mutect2, varscan2
- ABHD1 | c.521G>T p.C174F | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53205730, COSV53206463; called by muse, mutect2, varscan2
- ADAMTS6 | c.3191C>G p.S1064* | Nonsense Mutation (SNP) | VAF 39/97 reads (40%) | catalogued as COSV58681735; called by muse, mutect2, varscan2
- AJM1 | c.1292C>G p.T431S | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT tolerated (0.42); PolyPhen benign (0.067); catalogued as rs1183455203, COSV56032652; called by muse, mutect2, varscan2
- ALDH1A3 | c.1282G>A p.V428M | Missense Mutation (SNP) | VAF 99/147 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV60901548; called by muse, mutect2, varscan2
- ALDH8A1 | c.1350C>G p.I450M | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated (0.14); PolyPhen benign (0.156); catalogued as COSV55641313; called by muse, varscan2
- ALDH8A1 | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV55641342; called by muse, varscan2
- ALDH8A1 | c.1036C>G p.L346V | Missense Mutation (SNP) | VAF 56/81 reads (69%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV55641351; called by muse, mutect2, varscan2
- ALMS1 | c.7600G>T p.E2534* | Nonsense Mutation (SNP) | VAF 7/71 reads (10%) | catalogued as COSV100042499; called by muse, mutect2, varscan2
- ANGPTL5 | c.688A>G p.I230V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.06); catalogued as rs762486231, COSV57532769; called by muse, mutect2, varscan2
- ANKRD30A | c.3734A>T p.N1245I (on ENST00000611781; = p.N1189I on NM_052997.2) | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV64608836; called by muse, mutect2, varscan2
- AOPEP | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV52917196; called by muse, mutect2, varscan2
- ARHGAP35 | c.3711C>G p.I1237M | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.583); catalogued as COSV68330668; called by muse, mutect2, varscan2
- ARRDC5 | c.115G>T p.G39W (on ENST00000381781; = p.G25W on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67787913; called by muse, mutect2, varscan2
- ASAP2 | c.901A>T p.N301Y | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55630358, COSV55631077; called by muse, mutect2, varscan2
- ATF7IP | c.782C>G p.S261C | Missense Mutation (SNP) | VAF 89/132 reads (67%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.847); catalogued as COSV53769755; called by muse, mutect2, varscan2
- BAHCC1 | c.7512C>G p.F2504L | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV57025624; called by muse, mutect2, varscan2
- BRCA1 | c.90G>C p.L30F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58788540, COSV58788661; called by muse, mutect2, varscan2
- BUB1B | c.2290G>T p.E764* | Nonsense Mutation (SNP) | VAF 28/46 reads (61%) | catalogued as COSV55012726; called by muse, varscan2
- BUB1B | c.2357G>C p.R786T | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV55011976; called by muse, varscan2
- C10orf53 | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as rs1366313114, COSV65108651, COSV65108732; called by muse, mutect2, varscan2
- C12orf54 | c.284G>C p.R95T | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.037); catalogued as COSV100011703, COSV58360234; called by muse, mutect2, varscan2
- C2orf16 | c.2665C>G p.L889V | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62675120; called by muse, mutect2, varscan2
- C4B | c.3505-1G>T p.X1169_splice | Splice Site (SNP) | VAF 46/70 reads (66%) | catalogued as COSV70313359; called by muse, mutect2, varscan2
- CABP1 | c.682G>A p.E228K (on ENST00000316803 / NM_001033677.1; = p.E25K on NM_004276.5) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.318); catalogued as COSV56458402; called by muse, mutect2, varscan2
- CACNA1A | c.1833G>A p.M611I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV64196207; called by muse, mutect2, varscan2
- CAMK4 | c.127A>C p.S43R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV56669342; called by muse, mutect2, varscan2
- CATSPERB | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.29); PolyPhen benign (0.277); catalogued as COSV56425352; called by muse, mutect2, varscan2
- CCDC146 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99592606; called by muse, mutect2, varscan2
- CCDC157 | c.226C>A p.L76M | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1434012458, COSV57838704; called by muse, mutect2, varscan2
- CD79A | c.79+1G>A p.X27_splice | Splice Site (SNP) | VAF 6/45 reads (13%) | catalogued as COSV55739552, COSV99701999; called by muse, mutect2
- CDKN1A | c.66del p.F22Lfs*9 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | catalogued as COSV55188640; called by mutect2, pindel, varscan2
- CEMIP | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV54991504; called by muse, mutect2, varscan2
- CEP70 | c.1050+2T>C p.X350_splice | Splice Site (SNP) | VAF 37/197 reads (19%) | catalogued as COSV53875343; called by muse, mutect2, varscan2
- CEP89 | c.1804C>T p.H602Y | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV59863741; called by muse, mutect2, varscan2
- CFAP94 | c.1735C>T p.H579Y (on ENST00000320267 / NM_001352064.2; = p.H585Y on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.074); catalogued as COSV57231681; called by muse, mutect2, varscan2
- CHAC2 | c.340G>C p.D114H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs1284839030, COSV54857925; called by muse, mutect2, varscan2
- CHD8 | c.3171G>C p.Q1057H (on ENST00000646647 / NM_001170629.2; = p.Q778H on NM_020920.4) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1165718333, COSV67870304; called by muse, mutect2, varscan2
- CHRNB3 | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51494614; called by muse, mutect2, varscan2
- CIC | c.577A>T p.N193Y | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1404202625, COSV50561197; called by muse, mutect2, varscan2
- CLK3 | c.518C>T p.S173F (on ENST00000395066 / NM_001130028.1; = p.S25F on NM_003992.4) | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1208398085, COSV61412409; called by muse, mutect2, varscan2
- CLOCK | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV59401515; called by muse, mutect2, varscan2
- COL14A1 | c.361del p.E121Kfs*27 | Frame Shift Del (DEL) | VAF 22/145 reads (15%) | catalogued as COSV52852677; called by mutect2, pindel, varscan2
- COL27A1 | c.3971G>A p.G1324E | Missense Mutation (SNP) | VAF 39/43 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61921341; called by muse, mutect2, varscan2
- CPEB2 | c.2816G>A p.R939Q | Missense Mutation (SNP) | VAF 86/149 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs1224345591, COSV52589970; called by muse, mutect2, varscan2
- CPZ | c.196C>T p.Q66* (on ENST00000360986 / NM_001014447.3; = p.Q55* on NM_003652.3) | Nonsense Mutation (SNP) | VAF 36/56 reads (64%) | catalogued as COSV100248981; called by muse, mutect2, varscan2
- CROCC | c.4633G>C p.E1545Q | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.05); PolyPhen benign (0.234); catalogued as COSV100978197, COSV65011610; called by muse, mutect2, varscan2
- CRYBG2 | c.360G>C p.Q120H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as COSV57485409; called by muse, mutect2, varscan2
- CS | c.748C>G p.Q250E | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60832752; called by muse, mutect2, varscan2
- CSMD3 | c.5A>C p.K2T | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as COSV52161149; called by muse, mutect2, varscan2
- CTNNA2 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as rs760249011, COSV63561381; called by muse, mutect2, varscan2
- CYLD | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.538); catalogued as COSV61094157; called by muse, mutect2, varscan2
- CYSTM1 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated, low confidence (0.63); PolyPhen probably damaging (0.992); catalogued as rs867599794, COSV55834480; called by muse, mutect2
- DEF8 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1448619835, COSV51918781, COSV51919634; called by muse, mutect2, varscan2
- DENND2D | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62958985; called by muse, mutect2, varscan2
- DGKA | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59385708; called by muse, varscan2
- DISP3 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53825872, COSV99609367; called by muse, mutect2, varscan2
- DMAP1 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV60000463; called by muse, mutect2, varscan2
- DMXL2 | c.9050T>C p.L3017P | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51844845; called by muse, mutect2, varscan2
- DNAH8 | c.4786G>T p.G1596* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100545360; called by muse, mutect2, varscan2
- DNAH9 | c.6562G>A p.D2188N | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.443); catalogued as COSV52346126; called by muse, mutect2, varscan2
- DNAJC6 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV54781879; called by muse, mutect2
- DPF2 | c.373A>C p.T125P | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT tolerated (0.16); PolyPhen benign (0.063); catalogued as COSV52889003; called by muse, mutect2, varscan2
- DPP8 | c.1512C>G p.F504L (on ENST00000341861 / NM_001320875.2; = p.F488L on NM_017743.6) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs903255081, COSV55677829; called by muse, mutect2, varscan2
- EBF1 | c.931C>A p.R311S | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs768501688, COSV58175661; called by muse, mutect2, varscan2
- EMILIN3 | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.366); catalogued as rs1314022993, COSV60035911; called by muse, mutect2, varscan2
- EP400 | c.9137C>T p.A3046V | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.371); catalogued as rs150495795; called by muse, mutect2, varscan2
- EPHA6 | c.2041G>C p.E681Q (on ENST00000389672 / NM_001080448.3; = p.E73Q on NM_173655.4) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV67569602; called by muse, mutect2, varscan2
- ESRP1 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.796); catalogued as rs999647047, COSV100619667, COSV64409200; called by muse, mutect2, varscan2
- ETAA1 | c.1885G>C p.D629H | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV55472775; called by muse, varscan2
- EVI2B | c.442C>G p.Q148E | Missense Mutation (SNP) | VAF 60/293 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.164); catalogued as COSV58363751, COSV58363888; called by muse, mutect2, varscan2
- FAM160A2 | c.2023G>C p.G675R (on ENST00000449352 / NM_001098794.2; = p.G689R on NM_032127.4) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.725); catalogued as COSV56410970; called by muse, mutect2, varscan2
- FAT4 | c.9208C>G p.P3070A | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV58681263; called by muse, mutect2, varscan2
- FCRL6 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 77/123 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58940914, COSV58941558; called by muse, mutect2, varscan2
- FKBP15 | c.3355C>G p.Q1119E | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.039); catalogued as COSV53034023; called by muse, mutect2, varscan2
- FKBP15 | c.3112C>G p.L1038V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.015); catalogued as rs1450176116, COSV53034043; called by muse, mutect2, varscan2
- FOXO1 | c.627G>C p.W209C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs1314229602, COSV65426459; called by muse, mutect2, varscan2
- FRG2B | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs1340928236, COSV101423520; called by muse, mutect2
- FSTL4 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as rs754029268, COSV54768673; called by muse, mutect2, varscan2
- GAP43 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV59343769; called by muse, mutect2, varscan2
- GIGYF2 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV65248597; called by muse, mutect2, varscan2
- GLYATL2 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as rs186979803, COSV54849746, COSV99780579; called by muse, mutect2, varscan2
- GMNN | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57776534; called by muse, mutect2, varscan2
- GPATCH8 | c.3652G>A p.D1218N | Missense Mutation (SNP) | VAF 75/128 reads (59%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as rs987697969, COSV59194489; called by muse, mutect2, varscan2
- GPLD1 | c.632C>T p.S211L | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV57756450; called by muse, mutect2, varscan2
- GRIA4 | c.2411A>G p.D804G | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV56892661; called by muse, mutect2, varscan2
- H1-2 | c.327G>C p.K109N | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59190495, COSV59190892; called by muse, mutect2, varscan2
- HARS1 | c.793G>T p.D265Y | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56906475; called by muse, mutect2, varscan2
- HCRTR2 | c.381C>G p.C127W | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63795321; called by muse, mutect2
- HDHD5 | c.1251G>C p.K417N (on ENST00000336737 / NM_033070.3; = p.K387N on NM_017829.5) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.131); catalogued as COSV50085312; called by muse, mutect2, varscan2
- HEATR4 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58571763; called by muse, mutect2, varscan2
- HEATR5B | c.1366C>T p.H456Y | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.723); catalogued as COSV51852072; called by muse, mutect2, varscan2
- HIVEP3 | c.5240G>A p.R1747Q | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769827954, COSV56014043; called by muse, mutect2, varscan2
- HMCN1 | c.13753+1G>A p.X4585_splice | Splice Site (SNP) | VAF 5/41 reads (12%) | catalogued as COSV54894890; called by muse, mutect2, varscan2
- IARS1 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs201564889, COSV65114878; called by muse, mutect2, varscan2
- IFNK | c.205C>G p.P69A | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV51779322; called by muse, mutect2, varscan2
- IFNW1 | c.239T>A p.L80H | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs1317694382, COSV66521999; called by muse, mutect2, varscan2
- IL10RA | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99923095; called by muse, mutect2, varscan2
- IL16 | c.1077G>C p.Q359H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV57262721; called by muse, mutect2, varscan2
- INPPL1 | c.246G>A p.Q82= | Splice Region (SNP) | VAF 23/78 reads (29%) | catalogued as COSV53354900; called by muse, mutect2, varscan2
- IQCA1 | c.2271G>C p.Q757H | Missense Mutation (SNP) | VAF 51/59 reads (86%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV54499303, COSV54506384; called by muse, mutect2, varscan2
- IRF2 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV66929239; called by muse, mutect2, varscan2
- IRS1 | c.2815G>C p.E939Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.806); catalogued as COSV100524607, COSV59335663; called by muse, mutect2, varscan2
- JRKL | c.1010A>C p.N337T | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.111); catalogued as COSV99567317; called by muse, mutect2
- JUND | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV53254587; called by muse, mutect2, varscan2
- KAT6A | c.4423C>T p.H1475Y | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); catalogued as COSV55905369; called by muse, mutect2, varscan2
- KDM3A | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs951988563, COSV57219297, COSV57220428; called by muse, mutect2, varscan2
- KDM3B | c.4033G>A p.E1345K | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV58689968; called by muse, mutect2, varscan2
- KDM7A | c.279G>C p.L93F | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV50090999; called by muse, mutect2, varscan2
- KEL | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 53/86 reads (62%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.707); catalogued as COSV62334540, COSV62334856; called by muse, mutect2, varscan2
- KIAA1109 | c.12312G>C p.Q4104H | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.121); catalogued as rs1270137886, COSV52669984; called by muse, mutect2, varscan2
- KIAA1549 | c.2137C>T p.R713C | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.132); catalogued as rs766782097, COSV54306797; called by muse, mutect2, varscan2
- KIF3A | c.43G>T p.V15L | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as COSV66414225; called by muse, mutect2, varscan2
- KLHL28 | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 88/115 reads (77%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.988); catalogued as COSV61887957; called by muse, mutect2, varscan2
- KLHL31 | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV63881738; called by muse, mutect2, varscan2
- KLHL5 | c.2056G>A p.D686N | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.85); catalogued as COSV54673779; called by muse, mutect2, varscan2
- KMT2D | c.12133C>T p.Q4045* | Nonsense Mutation (SNP) | VAF 10/18 reads (56%) | catalogued as COSV56497034; called by muse, mutect2, varscan2
- KY | c.495G>C p.K165N | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as COSV101414991; called by muse, varscan2
- LAMA2 | c.7437G>A p.L2479= | Splice Region (SNP) | VAF 30/56 reads (54%) | catalogued as COSV70345102, COSV70355030; called by muse, mutect2, varscan2
- LAMA4 | c.2167G>A p.E723K (on ENST00000230538 / NM_001105206.3; = p.E716K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.92); catalogued as COSV57895732; called by muse, mutect2, varscan2
- LAMB2 | c.5152G>T p.E1718* | Nonsense Mutation (SNP) | VAF 38/76 reads (50%) | catalogued as COSV100026169; called by muse, mutect2, varscan2
- LGI1 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.222); catalogued as COSV65057895; called by mutect2, varscan2
- LPP | c.1417C>G p.L473V | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV57087748; called by muse, mutect2, varscan2
- LRPPRC | c.2868G>C p.Q956H | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV53237426; called by muse, varscan2
- LRRC49 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs1349516459, COSV53009996; called by muse, mutect2, varscan2
- MBP | c.52-1G>T p.X18_splice | Splice Site (SNP) | VAF 37/40 reads (93%) | catalogued as COSV63557417, COSV63557453; called by muse, mutect2, varscan2
- MGA | c.7859C>G p.S2620C (on ENST00000219905 / NM_001164273.1; = p.S2411C on NM_001080541.2) | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); catalogued as rs1235350315, COSV54950212, COSV54952608; called by muse, mutect2
- MMP13 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.106); catalogued as rs1555017148, COSV52823714; called by muse, mutect2, varscan2
- MPND | c.325G>C p.D109H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53656895; called by muse, mutect2, varscan2
- MPP7 | c.988G>C p.D330H | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs749658266, COSV61731685; called by muse, mutect2, varscan2
- MSANTD2 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.992); catalogued as COSV99515551; called by muse, mutect2, varscan2
- MTHFD2L | c.306G>C p.K102N (on ENST00000395759 / NM_001144978.2; = p.K44N on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/92 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57466979; called by muse, mutect2, varscan2
- MUC5AC | c.14194C>T p.P4732S | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.382); catalogued as COSV64369359; called by muse, mutect2, varscan2
- MYH11 | c.4738C>T p.L1580F | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55550716; called by muse, mutect2, varscan2
- MYO5A | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV62559371; called by muse, mutect2, varscan2
- MYT1L | c.3359C>A p.A1120E | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV101216703, COSV101217154; called by muse, mutect2, varscan2
- NDE1 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61271974; called by muse, mutect2, varscan2
- NDUFAF2 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs1209299036, COSV99681367; called by muse, mutect2, varscan2
- NF2 | c.1675G>T p.D559Y | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as rs917012886, COSV58522883, COSV58531921; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLK | c.1240A>G p.K414E | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.462); catalogued as COSV69408547; called by muse, mutect2, varscan2
- NOL4 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52345235, COSV99305406; called by muse, mutect2, varscan2
- NPTX1 | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV60774762, COSV60775812; called by muse, mutect2, varscan2
- NRDE2 | c.2542C>T p.H848Y | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.253); catalogued as COSV62962924; called by muse, varscan2
- NUP205 | c.1011G>T p.L337F | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53658010, COSV53662926; called by muse, mutect2, varscan2
- OBSCN | c.11179G>A p.E3727K | Missense Mutation (SNP) | VAF 82/166 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV52766396; called by muse, mutect2, varscan2
- OBSCN | c.12035G>A p.R4012H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs768635619, COSV52766430; called by muse, varscan2
- OR10Z1 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 91/142 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100778966, COSV63524575; called by muse, mutect2, varscan2
- OR13C9 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1467662038, COSV52241679; called by muse, mutect2, varscan2
- OR14J1 | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.221); catalogued as COSV65845636, COSV65845887; called by muse, mutect2, varscan2
- OR4N2 | c.284G>C p.R95T | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.028); catalogued as rs1186541677, COSV60051058, COSV60054174; called by muse, mutect2, varscan2
- OR51G1 | c.424T>C p.C142R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773967369, COSV58969020; called by muse, mutect2, varscan2
- OVOL2 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV99602459; called by muse, varscan2
- PAK3 | c.1636C>G p.L546V (on ENST00000262836 / NM_001324328.2; = p.L531V on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/46 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV53273502; called by muse, mutect2, varscan2
- PANK1 | c.1596G>A p.M532I (on ENST00000307534 / NM_148977.2; = p.M248I on NM_138316.4) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as rs1428311627, COSV56807750; called by muse, mutect2, varscan2
- PARP4 | c.1852G>A p.G618R | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV67961506; called by muse, mutect2, varscan2
- PBX2 | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66708824; called by muse, mutect2, varscan2
- PCDHA6 | c.1925C>G p.S642C | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as COSV65342335, COSV65343616; called by muse, mutect2, varscan2
- PCDHB6 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV50694563; called by muse, mutect2, varscan2
- PCF11 | c.919C>G p.H307D | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.728); catalogued as rs369620312, COSV100018408; called by muse, varscan2
- PCF11 | c.1714C>T p.Q572* | Nonsense Mutation (SNP) | VAF 21/45 reads (47%) | catalogued as COSV53532006; called by muse, mutect2, varscan2
- PDGFC | c.205A>G p.R69G | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1320903452, COSV56847936; called by muse, mutect2, varscan2
- PDXDC1 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.776); catalogued as COSV57906043; called by muse, mutect2
- PGP | c.856C>G p.L286V | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.429); catalogued as COSV57027664; called by muse, mutect2, varscan2
- PHAX | c.644A>G p.Y215C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as rs751056860, COSV52551007; called by muse, mutect2, varscan2
- PHLPP1 | c.3694G>C p.E1232Q | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV53027210; called by muse, mutect2, varscan2
- PI4KB | c.984C>A p.F328L (on ENST00000368873 / NM_001369623.1; = p.F340L on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as rs1318519438, COSV55016652; called by muse, mutect2, varscan2
- PIK3R4 | c.781C>G p.L261V | Missense Mutation (SNP) | VAF 75/101 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV63240510; called by muse, mutect2, varscan2
- PLCL2 | c.2724G>C p.L908F (on ENST00000615277 / NM_001144382.2; = p.L782F on NM_015184.5) | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV67621817; called by muse, mutect2, varscan2
- PLEKHA5 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1037502292, COSV54698930; called by muse, mutect2, varscan2
- POLQ | c.4289T>A p.L1430* | Nonsense Mutation (SNP) | VAF 47/69 reads (68%) | catalogued as rs377402875; called by muse, mutect2, varscan2
- POLR3H | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61749411; called by muse, mutect2, varscan2
- POTEF | c.1969A>G p.M657V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs746684750, COSV62540860; called by muse, mutect2, varscan2
- PRDM1 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 124/200 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV64845125; called by muse, mutect2, varscan2
- PRKAA1 | c.246C>G p.F82L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.489); catalogued as COSV57182977, COSV99713460; called by muse, mutect2, varscan2
- PRR5 | c.962G>C p.R321T (on ENST00000336985 / NM_181333.4; = p.R312T on NM_015366.4) | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.024); catalogued as COSV50059660; called by muse, mutect2, varscan2
- PRRC2C | c.3178C>T p.L1060F (on ENST00000367742; = p.L1058F on NM_015172.4) | Missense Mutation (SNP) | VAF 133/179 reads (74%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.188); catalogued as rs567117549, COSV58904286; called by muse, mutect2, varscan2
- PTPN22 | c.1748C>A p.S583Y (on ENST00000359785 / NM_001193431.2; = p.S528Y on NM_012411.5) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV63084483, COSV63084876; called by muse, mutect2, varscan2
- PZP | c.3895G>C p.D1299H | Missense Mutation (SNP) | VAF 76/106 reads (72%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV54358876; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1712C>T p.S571F | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54759539; called by muse, mutect2, varscan2
- RAET1G | c.663A>C p.Q221H | Missense Mutation (SNP) | VAF 34/36 reads (94%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as COSV66274233; called by muse, mutect2, varscan2
- RANBP2 | c.4411G>T p.D1471Y | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV51699951; called by muse, mutect2, varscan2
- RANBP3L | c.1135G>C p.E379Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs747964100, COSV56955293; called by muse, mutect2, varscan2
- RANGAP1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.218); catalogued as COSV62363222; called by muse, mutect2, varscan2
- RASSF2 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.631); catalogued as rs891733356, COSV101040824, COSV65082014; called by muse, mutect2, varscan2
- RESF1 | c.3274A>T p.K1092* | Nonsense Mutation (SNP) | VAF 21/65 reads (32%) | catalogued as COSV100440350; called by muse, mutect2, varscan2
- RFC2 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV50016100; called by muse, mutect2, varscan2
- RNF128 | c.695G>A p.R232Q (on ENST00000255499 / NM_194463.2; = p.R206Q on NM_024539.3) | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs766907592, COSV55250632; called by muse, mutect2, varscan2
- RNF215 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.805); catalogued as rs377398914; called by muse, mutect2, varscan2
- ROCK1 | c.1364C>A p.T455N | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1310390670, COSV101296321, COSV67695673; called by muse, mutect2, varscan2
- RSPH4A | c.392C>A p.S131* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV99994132; called by muse, mutect2, varscan2
- SARNP | c.378-1G>T p.X126_splice | Splice Site (SNP) | VAF 55/253 reads (22%) | catalogued as COSV60243105; called by muse, mutect2, varscan2
- SCD | c.672G>A p.M224I | Missense Mutation (SNP) | VAF 41/46 reads (89%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1043892903, COSV64853083; called by muse, mutect2, varscan2
- SCLT1 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV55404889; called by muse, mutect2, varscan2
- SCML2 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 68/74 reads (92%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV52620484; called by muse, varscan2
- SDK1 | c.3601C>G p.Q1201E | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV67365720; called by muse, mutect2, varscan2
- SEC24B | c.1816C>G p.R606G | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs993566753, COSV54498341; called by muse, mutect2, varscan2
- SETD2 | c.6230G>A p.R2077Q | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs981018402, COSV57435899; called by muse, mutect2, varscan2
- SH3GL2 | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV66049891; called by muse, mutect2, varscan2
- SKIV2L | c.3601C>G p.Q1201E | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV61713368; called by muse, mutect2, varscan2
- SLC12A7 | c.2041G>T p.E681* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as rs1355894376, COSV53757276, COSV99369889; called by muse, mutect2, varscan2
- SLC1A2 | c.1679C>T p.S560L | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.027); catalogued as COSV53520745, COSV53525149; called by muse, mutect2, varscan2
- SLC2A2 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV58585709; called by muse, mutect2, varscan2
- SLC35F3 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as rs1333828685, COSV100785313; called by muse, mutect2, varscan2
- SLC41A2 | c.259C>A p.H87N | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT tolerated (0.19); PolyPhen benign (0.047); catalogued as COSV51604203; called by muse, mutect2, varscan2
- SLC46A1 | c.744C>G p.H248Q | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV58708107; called by muse, mutect2, varscan2
- SLC5A5 | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM981846, COSV55832537; called by muse, mutect2, varscan2
- SLIT3 | c.4183G>A p.E1395K | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.698); catalogued as rs372131562; called by muse, mutect2, varscan2
- SLITRK3 | c.2629G>A p.G877S | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated, low confidence (0.47); PolyPhen probably damaging (0.934); catalogued as COSV53847812; called by muse, mutect2, varscan2
- SLU7 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs1341621526, COSV51787439; called by muse, mutect2, varscan2
- SNW1 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55053985; called by muse, mutect2, varscan2
- SNX6 | c.376G>A p.E126K (on ENST00000652385; = p.E114K on NM_152233.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/59 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV61918326; called by muse, mutect2, varscan2
- SP5 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as rs1339563908, COSV64623137; called by muse, mutect2, varscan2
- SPEG | c.2975C>T p.A992V | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.265); catalogued as rs766108579, COSV56666245; called by muse, mutect2, varscan2
- SPOCK3 | c.198G>T p.E66D | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV62723893; called by muse, mutect2, varscan2
- SPTA1 | c.4112A>T p.Q1371L | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.395); catalogued as COSV63752097; called by muse, mutect2, varscan2
- SRPRB | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs759544533, COSV72048417; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.909_910del p.F304Pfs*10 | Frame Shift Del (DEL) | VAF 24/93 reads (26%) | catalogued as rs1303170380; called by pindel, varscan2
- STAG2 | c.1689C>G p.I563M | Missense Mutation (SNP) | VAF 48/54 reads (89%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV54356438, COSV54374796, COSV99495076; called by muse, mutect2, varscan2
- STAM | c.344G>A p.W115* | Nonsense Mutation (SNP) | VAF 30/189 reads (16%) | catalogued as COSV101092279; called by muse, mutect2, varscan2
- STAM | c.345G>A p.W115* | Nonsense Mutation (SNP) | VAF 30/187 reads (16%) | catalogued as COSV101092280; called by muse, mutect2, varscan2
- STARD13 | c.2410C>G p.Q804E (on ENST00000336934 / NM_001243476.3; = p.Q686E on NM_052851.3) | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1231618946, COSV55229768; called by muse, mutect2, varscan2
- STAT6 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs767265892, COSV55670576; called by muse, mutect2, varscan2
- STIP1 | c.1519A>G p.I507V | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.922); catalogued as COSV99656586; called by muse, mutect2
- STOML1 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1406637511, COSV57551460; called by muse, mutect2, varscan2
- STOML1 | c.835C>G p.Q279E | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57551471; called by muse, mutect2, varscan2
- STYXL2 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54804384; called by muse, mutect2, varscan2
- SWT1 | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV62254613; called by muse, mutect2, varscan2
- SYNE1 | c.12738G>A p.M4246I (on ENST00000367255 / NM_182961.4; = p.M4175I on NM_033071.3) | Missense Mutation (SNP) | VAF 80/92 reads (87%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1008169560, COSV54963744; called by muse, mutect2, varscan2
- SYT10 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 114/182 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.367); catalogued as rs1447277671, COSV57339686; called by muse, mutect2, varscan2
- SYT16 | c.347C>G p.S116* | Nonsense Mutation (SNP) | VAF 66/147 reads (45%) | catalogued as COSV70855121; called by muse, mutect2, varscan2
- TANC2 | c.3538G>A p.E1180K | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.478); catalogued as COSV67333497; called by muse, mutect2, varscan2
- TAOK3 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as COSV66825142; called by muse, mutect2, varscan2
- TARS3 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as rs1205986310, COSV60107932, COSV60108327; called by muse, mutect2, varscan2
- TAT | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.259); catalogued as COSV63532695; called by muse, mutect2, varscan2
- TBC1D16 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV60477158; called by muse, varscan2
- TBC1D16 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as rs777334677, COSV100188054; called by muse, varscan2
- TBC1D4 | c.2602G>C p.D868H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV66488855; called by muse, mutect2, varscan2
- TDP1 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59642983, COSV59644042; called by muse, mutect2, varscan2
- TENM3 | c.7279C>T p.P2427S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.61); catalogued as rs762799784, COSV69305744; called by muse, mutect2, varscan2
- TENT4A | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.249); catalogued as rs766876723, COSV50095100, COSV50095698; called by muse, mutect2, varscan2
- TENT4A | c.1392G>C p.E464D | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.101); catalogued as COSV100048528, COSV50095404; called by muse, mutect2, varscan2
- TGM4 | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT tolerated (0.35); PolyPhen benign (0.209); catalogued as COSV56093652; called by muse, mutect2, varscan2
- TMEFF2 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 120/146 reads (82%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.713); catalogued as COSV55831613; called by muse, varscan2
- TMEM108 | c.1603G>C p.E535Q | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as COSV58864217, COSV58866121, COSV58870157; called by muse, mutect2, varscan2
- TMEM145 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV56624911; called by muse, mutect2, varscan2
- TMEM63C | c.1370C>G p.S457C | Missense Mutation (SNP) | VAF 97/216 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV53603055; called by muse, mutect2, varscan2
- TOR1AIP2 | c.877C>G p.P293A | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62625975; called by muse, mutect2, varscan2
- TP53 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 26/30 reads (87%) | catalogued as CM044725, COSV52746809, COSV52814837, COSV53366474; called by muse, mutect2, varscan2
- TRPM6 | c.1065C>G p.F355L | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV62508252; called by muse, mutect2, varscan2
- TTC21A | c.3356C>G p.S1119* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV99826885; called by muse, mutect2, varscan2
- TTC3 | c.3799G>A p.E1267K | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as COSV61289512; called by muse, mutect2, varscan2
- TTN | c.76148C>A p.S25383* (on ENST00000591111; = p.S17959* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 14/347 reads (4%) | catalogued as COSV100613010, COSV100617126; called by muse, mutect2
- TTN | c.55830G>C p.K18610N (on ENST00000591111; = p.K11186N on NM_003319.4) | Missense Mutation (SNP) | VAF 60/443 reads (14%) | PolyPhen probably damaging (0.997); catalogued as rs756340284, COSV60005010; called by muse, mutect2, varscan2
- TXNIP | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV65220333; called by muse, mutect2, varscan2
- TYRO3 | c.306C>G p.L102= | Splice Region (SNP) | VAF 10/41 reads (24%) | catalogued as COSV55482756; called by muse, mutect2
- UGT2B17 | c.1357C>G p.Q453E | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58501296; called by muse, mutect2, varscan2
- UNC5C | c.505T>C p.F169L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV71659132; called by muse, mutect2, varscan2
- UPK1B | c.262C>T p.L88F | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51766738; called by muse, mutect2, varscan2
- URB2 | c.3163C>T p.L1055F | Missense Mutation (SNP) | VAF 70/99 reads (71%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.634); catalogued as COSV50985755; called by muse, mutect2, varscan2
- USP37 | c.750G>C p.L250F | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV51442952; called by muse, mutect2, varscan2
- USP43 | c.2650G>C p.E884Q | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT tolerated (0.29); PolyPhen benign (0.073); catalogued as COSV53301600; called by muse, mutect2, varscan2
- USP47 | c.1399G>C p.E467Q (on ENST00000399455 / NM_001372095.1; = p.E379Q on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.403); catalogued as COSV60463065; called by muse, mutect2, varscan2
- USP6NL | c.1394A>G p.N465S | Missense Mutation (SNP) | VAF 90/276 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV53210725; called by muse, mutect2, varscan2
- USP9X | c.2482G>A p.D828N | Missense Mutation (SNP) | VAF 54/55 reads (98%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs746695479, COSV61068515; called by muse, mutect2, varscan2
- WDR35 | c.1724_1726del p.R575_V576delinsL (on ENST00000345530 / NM_001006657.2; = p.R564_V565delinsL on NM_020779.4) | In Frame Del (DEL) | VAF 118/180 reads (66%) | catalogued as COSV55602254; called by mutect2, pindel, varscan2
- WDR47 | c.140A>G p.D47G | Missense Mutation (SNP) | VAF 140/233 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63057774; called by muse, mutect2, varscan2
- WDR62 | c.3520G>A p.A1174T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV54334325; called by muse, mutect2, varscan2
- WNT16 | c.214G>C p.E72Q (on ENST00000222462 / NM_057168.2; = p.E62Q on NM_016087.2) | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV55975451, COSV99743602; called by muse, mutect2, varscan2
- XKR3 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV58885815; called by muse, mutect2, varscan2
- ZFYVE1 | c.1191C>G p.F397L | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV59610923; called by muse, mutect2, varscan2
- ZIC1 | c.1060C>T p.H354Y | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV51552753; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2158A>G p.I720V | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV60156556; called by muse, mutect2, varscan2
- ZMYM6 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV58184155; called by muse, mutect2, varscan2
- ZNF107 | c.266C>G p.S89* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV61329853; called by muse, mutect2, varscan2
- ZNF14 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.065); catalogued as rs1403712694, COSV59849264; called by muse, mutect2, varscan2
- ZNF30 | c.394G>C p.D132H | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV57853625; called by muse, mutect2, varscan2
- ZNF366 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); catalogued as rs932317991, COSV59213782; called by muse, mutect2, varscan2
- ZNF383 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.351); catalogued as COSV61939043; called by muse, mutect2, varscan2
- ZNF485 | c.733A>C p.N245H | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV62424188; called by muse, mutect2, varscan2
- ZNF529 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.076); catalogued as COSV61900045, COSV61900172; called by muse, mutect2, varscan2
- ZNF544 | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV54135648; called by muse, mutect2, varscan2
- ZNF626 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV74129389; called by muse, mutect2, varscan2
- ZNF639 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 72/134 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV58383100; called by muse, varscan2
- ZNF639 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 62/110 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV58383112; called by muse, varscan2
- ZNF653 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs1167493887, COSV53402646; called by muse, mutect2, varscan2
- ZNF692 | c.1372G>C p.E458Q | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777231968, COSV60637807; called by muse, mutect2, varscan2
- ZNF692 | c.1154-1G>C p.X385_splice | Splice Site (SNP) | VAF 13/35 reads (37%) | catalogued as COSV60637812; called by muse, mutect2, varscan2
- ZNF710 | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as rs1307220401, COSV51562738; called by muse, mutect2, varscan2
- ZNF765 | c.1260C>G p.F420L | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV67182399; called by muse, mutect2, varscan2
- ZNF768 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53223619; called by muse, mutect2, varscan2
- ZSCAN4 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as COSV99990002; called by muse, mutect2, varscan2
- KMT2C | c.10643del p.P3548Qfs*2 | Frame Shift Del (DEL) | VAF 20/34 reads (59%) | called by mutect2, pindel, varscan2
- MBLAC2 | c.359T>C p.L120P | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2
- SEZ6 | c.1381_1383del p.K461del | In Frame Del (DEL) | VAF 24/170 reads (14%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.2164G>C p.E722Q | Missense Mutation (SNP) | VAF 35/35 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.187); called by mutect2, varscan2
- VPS72 | c.907G>C p.D303H | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZZEF1 | c.3484-6_3488del p.X1162_splice | Splice Site (DEL) | VAF 60/107 reads (56%) | called by mutect2, pindel, varscan2
- ABCA7 | c.3126G>A p.L1042= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV54028103; called by muse, mutect2, varscan2
- ACSM2B | c.1416G>C p.R472= | Silent (SNP) | VAF 44/86 reads (51%) | catalogued as COSV61657571; called by muse, mutect2, varscan2
- AHNAK2 | c.8997C>T p.V2999= | Silent (SNP) | VAF 235/491 reads (48%) | catalogued as COSV60913840; called by muse, mutect2, varscan2
- ALDH8A1 | c.1275C>T p.S425= | Silent (SNP) | VAF 28/40 reads (70%) | catalogued as COSV55641328; called by muse, varscan2
- AMPD2 | c.1248G>A p.L416= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs1163184361, COSV56647345; called by muse, mutect2, varscan2
- ANKRD6 | c.159C>G p.G53= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1384482502, COSV60230826; called by muse, mutect2, varscan2
- ANKS3 | c.1320G>C p.L440= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs773600265, COSV58508692; called by muse, mutect2, varscan2
- BICRA | c.4464C>T p.S1488= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as rs771473550, COSV67604533; called by muse, varscan2
- CACNA1B | c.5196C>G p.V1732= | Silent (SNP) | VAF 26/49 reads (53%) | catalogued as COSV53123143; called by muse, mutect2, varscan2
- CALML3 | c.384C>T p.A128= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as rs35269869, COSV100178889, COSV59449289; called by muse, mutect2
- CDCP2 | c.1251C>T p.L417= | Silent (SNP) | VAF 22/32 reads (69%) | catalogued as COSV61283541; called by muse, mutect2, varscan2
- CIC | c.2892C>T p.I964= | Silent (SNP) | VAF 32/90 reads (36%) | catalogued as rs371872768; called by muse, mutect2, varscan2
- CLCN5 | c.168C>T p.S56= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs782057466, COSV56583573; called by muse, mutect2, varscan2
- CLTCL1 | c.4389G>C p.V1463= | Silent (SNP) | VAF 59/178 reads (33%) | catalogued as COSV54229024; called by muse, mutect2, varscan2
- CSMD2 | c.1368C>A p.G456= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV53905176; called by muse, mutect2, varscan2
- DCAF17 | c.1197C>G p.L399= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV59830156; called by muse, mutect2, varscan2
- DMXL2 | c.9051G>T p.L3017= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV51844834; called by muse, mutect2, varscan2
- DRC1 | c.1911G>A p.K637= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV55501350; called by muse, mutect2, varscan2
- ELMO2 | c.789C>G p.L263= | Silent (SNP) | VAF 36/163 reads (22%) | catalogued as COSV51682517; called by muse, mutect2, varscan2
- EML4 | c.12C>T p.F4= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs1321827535, COSV59296728; called by muse, mutect2
- FAM204A | c.72G>A p.T24= | Silent (SNP) | VAF 30/34 reads (88%) | catalogued as rs748820757, COSV64987653; called by muse, mutect2, varscan2
- FBH1 | c.123C>T p.L41= (on ENST00000362091 / NM_178150.3; = p.L92= on NM_032807.4) | Silent (SNP) | VAF 47/121 reads (39%) | catalogued as COSV62982345; called by muse, mutect2, varscan2
- FCGBP | c.9015C>T p.P3005= | Silent (SNP) | VAF 84/207 reads (41%) | called by muse, varscan2
- FLNB | c.7566C>T p.L2522= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV55877530; called by muse, mutect2, varscan2
- FRMD1 | c.261G>A p.A87= | Silent (SNP) | VAF 66/120 reads (55%) | catalogued as rs1562426442, COSV51961470, COSV99349574; called by muse, mutect2, varscan2
- GBA3 | c.996T>A p.I332= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV101545515; called by muse, mutect2
- HCFC1R1 | c.105C>T p.L35= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99560608; called by muse, mutect2
- HEATR4 | c.549G>C p.V183= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV58571779; called by muse, mutect2, varscan2
- HOXA13 | c.1131G>A p.E377= | Silent (SNP) | VAF 59/313 reads (19%) | catalogued as COSV56082891, COSV56083283; called by muse, mutect2, varscan2
- IHO1 | c.36C>T p.L12= | Silent (SNP) | VAF 48/86 reads (56%) | catalogued as rs1223397583, COSV56507321; called by muse, mutect2, varscan2
- IL1R2 | c.495G>A p.V165= | Silent (SNP) | VAF 59/122 reads (48%) | catalogued as COSV60206477; called by muse, mutect2, varscan2
- INTS3 | c.2082G>A p.L694= | Silent (SNP) | VAF 74/218 reads (34%) | catalogued as COSV59676920; called by muse, mutect2, varscan2
- ITGB2 | c.471C>T p.L157= | Silent (SNP) | VAF 48/88 reads (55%) | catalogued as COSV56609636; called by muse, mutect2, varscan2
- ITSN2 | c.1413C>T p.L471= | Silent (SNP) | VAF 17/170 reads (10%) | catalogued as COSV61946160; called by muse, mutect2, varscan2
- KCTD17 | c.405C>T p.V135= | Silent (SNP) | VAF 20/25 reads (80%) | catalogued as COSV63248881; called by muse, mutect2, varscan2
- KIAA0513 | c.231C>T p.S77= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV50741074; called by muse, mutect2, varscan2
- KLF9 | c.585G>A p.R195= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV65807568; called by muse, mutect2, varscan2
- KRT77 | c.513C>T p.L171= | Silent (SNP) | VAF 43/135 reads (32%) | catalogued as COSV59239434; called by muse, mutect2, varscan2
- LEPR | c.2220C>T p.I740= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs757501135, COSV60750793; called by mutect2, varscan2
- LILRA6 | c.1146C>T p.P382= | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as COSV99557737; called by muse, mutect2
- LILRB3 | c.1146C>T p.P382= | Silent (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- MAMDC4 | c.1068C>G p.L356= | Silent (SNP) | VAF 35/38 reads (92%) | catalogued as rs757513093, COSV56032657; called by muse, mutect2, varscan2
- MAN2A2 | c.2505C>T p.V835= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV64638001; called by muse, mutect2, varscan2
- MAP1A | c.5991C>T p.P1997= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as rs760579428, COSV55808001; called by muse, mutect2, varscan2
- MAPK4 | c.486C>G p.L162= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV68541832; called by muse, mutect2, varscan2
- MCM3 | c.393C>G p.L131= (on ENST00000229854 / NM_001366374.2; = p.L121= on NM_002388.6 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV57717375; called by muse, mutect2, varscan2
- MEF2B | c.333G>A p.E111= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as COSV50762885; called by muse, mutect2, varscan2
- MEP1A | c.1989C>T p.D663= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV57920878, COSV57921097; called by muse, mutect2
- MGA | c.1200C>T p.V400= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as COSV54952595; called by muse, mutect2, varscan2
- MSLNL | c.1719C>T p.T573= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs763825643, COSV53501469; called by muse, mutect2, varscan2
- N4BP1 | c.588C>G p.L196= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV52210536; called by muse, mutect2, varscan2
- NLN | c.1317C>T p.L439= | Silent (SNP) | VAF 58/134 reads (43%) | catalogued as COSV66765648; called by muse, mutect2, varscan2
- NUP205 | c.3847C>T p.L1283= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as COSV53658021; called by muse, mutect2, varscan2
- OPRL1 | c.144C>T p.L48= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as rs755034870, COSV61091530; called by muse, mutect2, varscan2
- OSGIN2 | c.570G>A p.K190= | Silent (SNP) | VAF 26/158 reads (16%) | catalogued as rs760748640, COSV52408192; called by muse, mutect2, varscan2
- PCSK5 | c.639G>A p.G213= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV65084041; called by muse, mutect2, varscan2
- PDXDC1 | c.315G>A p.L105= | Silent (SNP) | VAF 14/249 reads (6%) | catalogued as COSV57906031; called by muse, mutect2
- PJA1 | c.768C>G p.V256= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV64052995; called by muse, mutect2, varscan2
- PNCK | c.240C>T p.H80= (on ENST00000340888 / NM_001366975.1; = p.H163= on NM_001039582.3) | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs142357600, COSV61743385; called by muse, mutect2, varscan2
- POLA2 | c.1320C>T p.F440= | Silent (SNP) | VAF 168/279 reads (60%) | catalogued as COSV55482571; called by muse, varscan2
- POLR1F | c.810C>T p.I270= | Silent (SNP) | VAF 324/650 reads (50%) | catalogued as COSV55998305; called by muse, mutect2, varscan2
- PRAME | c.639G>A p.L213= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV67161438; called by muse, mutect2, varscan2
- PSMA4 | c.684C>G p.L228= | Silent (SNP) | VAF 52/70 reads (74%) | catalogued as COSV50384611; called by muse, mutect2, varscan2
- PSME3IP1 | c.336G>A p.L112= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV58429064; called by muse, mutect2, varscan2
- PTPN22 | c.1371G>A p.Q457= (on ENST00000359785 / NM_001193431.2; = p.Q402= on NM_012411.5) | Silent (SNP) | VAF 65/105 reads (62%) | catalogued as COSV63084389, COSV63087025; called by muse, mutect2, varscan2
- PTPRR | c.897G>T p.L299= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV51730290; called by muse, mutect2, varscan2
- QARS1 | c.1095C>G p.L365= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as COSV60274730; called by muse, mutect2, varscan2
- RAB24 | c.123C>T p.I41= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV57463195; called by muse, mutect2, varscan2
- RANBP10 | c.987C>G p.L329= | Silent (SNP) | VAF 28/45 reads (62%) | catalogued as COSV58157255; called by muse, mutect2, varscan2
- RAPGEF5 | c.1602G>C p.L534= (on ENST00000401957 / NM_001367602.2; = p.L837= on NM_012294.5) | Silent (SNP) | VAF 79/160 reads (49%) | catalogued as COSV59781830; called by muse, mutect2, varscan2
- RGS9BP | c.63C>T p.H21= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs1369867023, COSV60130995; called by muse, mutect2, varscan2
- RIOX2 | c.1395C>G p.V465= (on ENST00000333396 / NM_001042533.2; = p.V464= on NM_032778.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 55/110 reads (50%) | catalogued as COSV51711345; called by muse, mutect2, varscan2
- RNF128 | c.522G>T p.L174= (on ENST00000255499 / NM_194463.2; = p.L148= on NM_024539.3) | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV55250606; called by muse, mutect2, varscan2
- SAE1 | c.306C>G p.L102= | Silent (SNP) | VAF 67/126 reads (53%) | catalogued as rs1184304443, COSV54294533; called by muse, mutect2, varscan2
- SCD | c.852G>A p.E284= | Silent (SNP) | VAF 24/25 reads (96%) | catalogued as rs1281398607, COSV64852803; called by muse, mutect2, varscan2
- SIGLEC1 | c.3756G>A p.T1252= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs200543891, COSV52462337; called by muse, mutect2, varscan2
- SMG5 | c.2394G>A p.Q798= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV62434952; called by muse, mutect2, varscan2
- SPAG17 | c.2073T>G p.P691= | Silent (SNP) | VAF 9/128 reads (7%) | catalogued as COSV60457360; called by muse, mutect2
- STAB2 | c.2457C>A p.A819= | Silent (SNP) | VAF 39/57 reads (68%) | catalogued as COSV66337992; called by muse, mutect2
- SYNE2 | c.1299G>C p.L433= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV59948217; called by muse, mutect2, varscan2
- TDP1 | c.1137G>A p.L379= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as COSV59642977; called by muse, mutect2, varscan2
- THSD4 | c.483C>G p.T161= | Silent (SNP) | VAF 60/247 reads (24%) | catalogued as COSV55968274; called by muse, mutect2, varscan2
- TM9SF3 | c.1383C>T p.I461= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs1408286988, COSV64457228; called by muse, mutect2, varscan2
- TRIB1 | c.1023C>T p.V341= | Silent (SNP) | VAF 18/134 reads (13%) | catalogued as COSV61334505; called by muse, mutect2, varscan2
- TSC2 | c.87G>A p.R29= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as rs1010489256, COSV54592815; called by muse, mutect2, varscan2
- TTC21A | c.1872C>T p.S624= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV57184626; called by muse, mutect2, varscan2
- TTN | c.43062C>A p.T14354= (on ENST00000591111; = p.T6930= on NM_003319.4) | Silent (SNP) | VAF 147/226 reads (65%) | catalogued as COSV60005048; called by muse, mutect2, varscan2
- TTN | c.29565C>T p.I9855= (on ENST00000591111; = p.I8928= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV60005092; called by muse, mutect2, varscan2
- TTN | c.12009C>T p.V4003= (on ENST00000591111; = p.V3957= on NM_003319.4) | Silent (SNP) | VAF 166/212 reads (78%) | catalogued as COSV100637280, COSV60005105; called by muse, mutect2, varscan2
- TUBB4A | c.285C>T p.S95= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs767100230, COSV51153954; called by muse, mutect2, varscan2
- WFIKKN2 | c.1488C>G p.L496= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV60958505; called by muse, mutect2, varscan2
- WIPI1 | c.712C>T p.L238= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV50929907; called by muse, mutect2, varscan2
- XPO5 | c.138C>T p.I46= | Silent (SNP) | VAF 41/70 reads (59%) | catalogued as COSV54829450; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1590C>G p.V530= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV54295172; called by muse, mutect2, varscan2
- ZNF112 | c.2214T>A p.G738= (on ENST00000337401 / NM_001083335.2; = p.G732= on NM_013380.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 44/134 reads (33%) | catalogued as rs376999795, COSV61619770; called by muse, mutect2, varscan2
- ZNF16 | c.372G>A p.R124= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV52763076; called by muse, mutect2, varscan2
- ZNF160 | c.1299C>A p.V433= | Silent (SNP) | VAF 6/148 reads (4%) | catalogued as COSV61999485; called by muse, mutect2
- ZNF432 | c.1827G>A p.K609= | Silent (SNP) | VAF 53/148 reads (36%) | catalogued as rs1342379604, COSV55416235; called by muse, mutect2, varscan2
- ZNF432 | c.810C>T p.F270= | Silent (SNP) | VAF 62/162 reads (38%) | catalogued as COSV55416246; called by muse, mutect2, varscan2
- ZNF501 | c.405A>G p.K135= | Silent (SNP) | VAF 4/82 reads (5%) | catalogued as COSV101247104; called by muse, mutect2
- ZNF606 | c.252G>A p.R84= | Silent (SNP) | VAF 64/206 reads (31%) | catalogued as COSV62046211; called by muse, mutect2, varscan2
- ALDH3A2 | c.1443+1212G>A | Intron (SNP) | VAF 59/478 reads (12%) | catalogued as COSV51566523; called by muse, mutect2, varscan2
- DENND10P1 | n.792C>G | RNA (SNP) | VAF 67/71 reads (94%) | called by muse, mutect2, varscan2
- KIR3DL2 | chr19:54847209 G>C | 5'Flank (SNP) | VAF 85/409 reads (21%) | called by muse, mutect2, varscan2
- MIR518C | n.44C>G | RNA (SNP) | VAF 40/84 reads (48%) | catalogued as rs1380964861; called by muse, mutect2, varscan2
- PCDHA8 | c.2394+25C>G | Intron (SNP) | VAF 12/27 reads (44%) | catalogued as COSV65325697; called by muse, mutect2, varscan2
- RPL12 | c.293-115C>T | Intron (SNP) | VAF 69/79 reads (87%) | catalogued as COSV100031503; called by muse, mutect2, varscan2
- SDC1 | c.*477C>T | 3'UTR (SNP) | VAF 25/31 reads (81%) | catalogued as rs762744656, COSV54339623, COSV99587185; called by muse, mutect2, varscan2
